Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3O0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3O0-01A (Primary Tumor).

[page 1 of 3]
FINAL DIAGNOSIS

- A) Thyroid, right lobe and isthmus, resection: Papillary carcinoma (see synoptic report).
- B) Thyroid, left lobe, completion thyroidectomy: Benign thyroid tissue.
- C) Lymph node, left paratracheal, biopsy: Three lymph nodes, parathyroid and thymic tissue with no evidence of malignancy.
- D) Central compartment: Thyroid tissue and fibroadipose tissue with no evidence of malignancy. No lymph nodes are seen.
- E) Paratracheal tissue, right: Fibroadipose tissue with no evidence of malignancy.

A: Thyroid Gland
HISTOLOGIC TYPE:
Papillary carcinoma
Follicular variant

ICD-0-3

carcinoma, papillary, follicular variant
8340/3

TUMOR SITE:
Right Lobe

Site: thyroid, nos C73.9

hw
2/6/12

TUMOR SIZE:
Greatest Dimension: 2.8 cm

PRIMARY TUMOR (pT):
pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid

REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis

NUMBER OF LYMPH NODE(S) INVOLVED: 0

NUMBER OF LYMPH NODE(S) EXAMINED: 3

DISTANT METASTASIS (pM):
pMX: Cannot be assessed

MARGINS:

[page 2 of 3]
Margins uninvolved by carcinoma

~electronic signature~

SPECIMEN RECEIVED

- A) RIGHT THYROID LOBE AND ISTHMUS, FS
- B) LEFT THYROID LOBE
- C) LEFT PARATRACHEAL LYMPH NODE
- D) CENTRAL COMPARTMENT LYMPH NODES
- E) RIGHT PARATRACHEAL TISSUE

FROZEN SECTION

Thyroid, right lobe, resection: Papillary carcinoma.

Seen with Dr. _____

GROSS DESCRIPTION

A) Received fresh for intraoperative consultation labeled "right thyroid lobe and isthmus." The specimen consists of a portion of dark red/purple thyroid tissue, overall measuring 8.3 x 5.5 x 3.0 cm, 30 grams. The specimen is inked and serially sectioned revealing a firm encapsulated mass measuring 2.8 x 2.7 x 2.5 cm. A representative section is submitted for frozen and subsequent permanent section evaluation in cassette A1. Touch preparations are prepared. The sections are submitted for frozen and subsequent permanent section evaluation in cassettes A1-A2. Additional sections are submitted for permanent sections as follows: Sections from mass submitted in cassettes A3-A5; section of uninvolved thyroid A6. Tissue is submitted for the

B) In formalin labeled "left thyroid lobe". The specimen consists of a portion of dark red to purple thyroid tissue measuring 5.0 x 3.3 x 1.8 cm, 11 grams. The specimen is inked and serially sectioned. Sectioning is unremarkable. Representative sections are submitted in cassettes B1-B6.

C) In formalin labeled "left paratracheal lymph node". The specimen consists of an ovoid portion of pink/tan soft tissue measuring 1.0 cm in greatest dimension. The specimen is bisected and submitted entirely in cassette C1.

D) In formalin labeled "central compartment lymph nodes". The specimen consists of an irregular portion of pink/tan soft tissue measuring 2.5 x 1.5 x 0.8 cm. The

[page 3 of 3]
specimen is dissected in search of lymph nodes. Multiple possible lymph nodes are identified. These are submitted whole in cassettes D1-D2.

E) In formalin labeled "right paratracheal tissue". The specimen consists of an ovoid portion of pink/tan soft tissue measuring 1.3 x 1.0 x 0.6 cm. The specimen is bisected and submitted entirely in cassette E1.

CLINICAL INFORMATION

RIGHT THYROID MASS

Source: NCI Genomic Data Commons file ee0a951a-6051-4124-8f6b-5291218ecc0c (TCGA-J8-A3O0.33E08AA4-5DD6-4C54-89C1-5EC2C548800F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).